Surgical pathology report (de-identified scan), TCGA case TCGA-FE-A22Z, project TCGA-THCA (Thyroid Carcinoma), tissue source site Ohio State University, specimen TCGA-FE-A22Z-01A (Primary Tumor).

[page 1 of 4]
Specimen Description

Surgical Pathology Report

Patient Name: [REDACTED]
Accession #: [REDACTED]
Med. Rec #: [REDACTED]
Submitting Physician: [REDACTED]

*****Clinical History*****
Thyroid cancer.

*****Final Pathologic Diagnosis*****

- A. Lymph node left level III, excision:
- One lymph node with no evidence of malignancy (0/1).
- B. Thyroid, right lobe, hemithyroidectomy:
- Benign thyroid parenchyma with focal foreign body giant cell reaction; negative for carcinoma.
- C. Soft tissue, central neck, excision:
- Fibroadipose tissue with focal fibrosis and foreign body giant cell reaction; negative for carcinoma.
- D. Thyroid, left lobe, hemithyroidectomy:
- Papillary thyroid carcinoma, follicular variant See Synoptic Report.
- Inked margin focally involved by carcinoma.
- E. "Paralaryngeal tissue", excision:
- Benign thyroid parenchyma with dilated follicle; negative for carcinoma.
- F. Soft tissue "involving thyroid cartilage", excision:
- Papillary thyroid carcinoma involving fibrous connective tissue and skeletal muscle.

Electronically Signed By
[REDACTED]
[REDACTED]

*****Synoptic Report*****

Specimen type: Thyroidectomy

ICC-0-3
carcinoma, papillary, follicular
variant 8340/3 lw 4/8/11
site: thyroid, NOS C73.9

[page 2 of 4]
Sex F
Rm/Bed

Specimen Description

Surgical Pathology Report

*****Clinical History*****
Thyroid cancer.

*****Final Pathologic Diagnosis*****

Lymph node left level III, excision:
One lymph node with no evidence of malignancy (0/1).

Thyroid, right lobe, hemithyroidectomy:
Benign thyroid parenchyma with focal foreign body giant cell reaction; negative for carcinoma.

Soft tissue, central neck, excision:
- Fibroadipose tissue with focal fibrosis and foreign body giant cell reaction; negative for carcinoma.

Thyroid, left lobe, hemithyroidectomy:
- Papillary thyroid carcinoma, follicular variant See Synoptic Report.
- Inked margin focally involved by carcinoma.

"Paralaryngeal tissue", excision:
- Benign thyroid parenchyma with dilated follicle; negative for carcinoma.

Soft tissue "involving thyroid cartilage", excision:
- Papillary thyroid carcinoma involving fibrous connective tissue and skeletal muscle.

*****Synoptic Report*****

Specimen type: Thyroidectomy
Tumor location: Left lobe
Tumor size: 6.5 x 5.0 x 3.0 cm

Histologic type: Papillary thyroid carcinoma, follicular variant
Lymphatic/vascular invasion: Not identified

[page 3 of 4]
Sex F
Rm/Bed

Capsular invasion: Present

Tumor extent:

Confined to the thyroid: No

Multifocal: No

Invasion of thyroid cartilage or hyoid bone: Soft tissue around thyroid cartilage is involved by carcinoma.

Infiltration of adjacent structures: Yes

Margins: Inked margin focally involved by carcinoma

Lymph nodes:

Total number examined: 1

Sites/laterality: Left Level III

Number positive: 0

Number negative: 1

The above synoptic report complies, in slightly modified form, with the guidelines of the College of American Pathologists and the Association of Directors of Anatomic and Surgical Pathology for the reporting of cancer specimens

*****SPECIMEN(S) RECEIVED:*****

: Lymph node, thoracic, REG
: Thyroid, REG
: Neck (not radical neck), REG
: Thyroid, REG
: Larynx, REG
: Soft tissue

*****GROSS DESCRIPTION:*****

The specimens are received in six properly labeled containers with the patient's name and accession number.

The specimen is designated "left Level III L.N." and consists of a 1.5 x 1.0 x 0.5 cm possible lymph node. The lymph node is bisected and entirely submitted. TE 1

The specimen is designated "right thyroid lobe" and consists of a 12.2 gram lobe of thyroid, which is 4.5 x 4.0 x 1.5 cm. The external surface is pink-brown and wrinkled, with no attached parathyroid gland or lymph nodes. The isthmus margin is inked green, and the external surface of the thyroid is inked blue. Sectioning reveals deep red, rubbery parenchyma with no discrete lesions. TE 9

Summary of Cassettes: B1, shaved isthmus margin; B2-9, remainder of lobe, submitted sequentially

The specimen is designated "central neck tissue" and consists of a 4.5 x 2.0 x 1.0 cm irregular portion of adipose tissue. Upon dissection, no lymph nodes are identified. TE 3

The specimen is designated "left thyroid lobe" and consists of a 47.2 gram lobe of thyroid, which is 6.5 x 6.0 x 3.0 cm. The external surface is tan-gray and diffusely shaggy. The isthmus margin cannot be identified. No parathyroid glands or lymph nodes are attached to the

[page 4 of 4]
Sex F
Rm/Bed

external surface. The entire lobe is inked black. Sectioning reveals a 6.5 x 5.0 x 3.0 cm infiltrative, tan-gray, firm, focally hemorrhagic mass. The mass abuts the black-inked capsule, however does not grossly invade through it. The hemorrhage comprises of approximately 20% of the total cut surfaces. The remaining, uninvolved thyroid parenchyma is pink-red and rubbery.

Summary of Cassettes: D1-5, sections of mass to capsule; D6-7, sections of mass to normal thyroid; D8, section of normal thyroid

● The specimen is designated "paralaryngeal tissue" and consists of a 0.9 x 0.7 x 0.3 cm irregular portion of red-brown skeletal muscle.

● The specimen is designated "tissue involving thyroid cartilage" and consists of seven irregular portions of tan-gray thyroid cartilage, which range from 1.0 x 0.6 x 0.1 cm up to 3.5 x 1.5 x 0.3 cm. The portions of cartilage have one wrinkled, pink-gray surface and an opposing focally granular/nodular tan-gray surface. The granularity and nodularity comprises approximately 30% of each portion of tissue.

Lab Use Only:

Lab Use Only:

Gross description by:

Source: NCI Genomic Data Commons file 3beaebf3-477c-419f-9dbf-43353340be99 (TCGA-FE-A22Z.710D01CA-DAD1-4A53-9CC4-A859A813656D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).